Somatic mutation profile of tumor specimen ALCH-ADNJ-TTP1-A (aliquot ALCH-ADNJ-TTP1-A-1-0-D-A565-36) from ALCHEMIST case ALCH-ADNJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma in situ, NOS; Age at diagnosis: 56.8 years (20,756 days).
Specimen ALCH-ADNJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2009af17-5153-4335-9ae6-331d48327e4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADNJ-NB1-A (Blood Derived Normal), aliquot ALCH-ADNJ-NB1-A-1-0-D-A565-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a58aa7b9-a855-460a-a3f7-a9f9ab763523

The open-access MAF lists 160 somatic variants for this specimen: 120 protein-altering or splice-affecting, 21 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 21, Intron 10, Nonsense Mutation 7, Frame Shift Del 5, 3'UTR 3, 5'UTR 3, Splice Site 2, RNA 2, Translation Start Site 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 68/432 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCD1 | c.1679C>A p.P560Q | Missense Mutation (SNP) | VAF 45/302 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM950052, CM960042, COSV99497942; called by muse, mutect2, varscan2
- AC006059.2 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs936126286; called by muse, mutect2, varscan2
- ADGRG2 | c.2942C>G p.T981S (on ENST00000379869 / NM_001079858.3; = p.T978S on NM_005756.4) | Missense Mutation (SNP) | VAF 37/322 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV61339053; called by muse, mutect2, varscan2
- ANKDD1A | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1292753210; called by muse, mutect2
- BIRC7 | c.563C>A p.P188H | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV99416791; called by muse, mutect2, varscan2
- C2CD2 | c.2074G>T p.V692L | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.095); catalogued as rs772837893; called by muse, mutect2, varscan2
- CDH10 | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 49/548 reads (9%) | catalogued as COSV52574944; called by muse, mutect2
- COLEC11 | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.339); catalogued as COSV52598860; called by muse, mutect2, varscan2
- CYP24A1 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 54/912 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs753774862, COSV53773071; called by muse, mutect2
- DPP6 | c.940G>A p.A314T (on ENST00000377770 / NM_001364500.2; = p.A252T on NM_001936.5) | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs778166866, COSV59599853; called by muse, mutect2, varscan2
- FAM155B | c.1283C>G p.P428R | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV52937626; called by muse, mutect2, varscan2
- FAT1 | c.322C>T p.L108F | Missense Mutation (SNP) | VAF 23/382 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71675492; called by muse, mutect2
- FCRL2 | c.717G>T p.W239C | Missense Mutation (SNP) | VAF 107/423 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779700382; called by muse, mutect2, varscan2
- GNS | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 44/828 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs746970479; called by muse, mutect2
- HEATR5B | c.5888T>C p.V1963A | Missense Mutation (SNP) | VAF 15/328 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs1302008653; called by muse, mutect2
- IFITM5 | c.226C>G p.R76G | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.304); catalogued as rs374350236; called by mutect2, varscan2
- INTS6L | c.1315G>T p.A439S | Missense Mutation (SNP) | VAF 38/412 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs782654510; called by muse, mutect2
- KCNK18 | c.737C>A p.A246D | Missense Mutation (SNP) | VAF 69/516 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as rs202105195; called by muse, mutect2, varscan2
- KPRP | c.619del p.Q207Sfs*4 | Frame Shift Del (DEL) | VAF 69/606 reads (11%) | catalogued as rs1160391112; called by mutect2, pindel, varscan2
- MANEAL | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs1557572099; called by muse, mutect2, varscan2
- MDGA1 | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 42/278 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV51791208; called by muse, mutect2, varscan2
- MUC16 | c.14951C>T p.T4984I | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.158); catalogued as rs369053006; called by muse, mutect2, varscan2
- MYH7B | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | catalogued as COSV99483237; called by muse, mutect2, varscan2
- NALCN | c.439C>G p.P147A | Missense Mutation (SNP) | VAF 84/554 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as COSV51967840; called by muse, mutect2, varscan2
- NLRP10 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 25/320 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.721); catalogued as rs529453927, COSV60781142; called by muse, mutect2
- NUP133 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 54/399 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54569664, COSV99773033; called by muse, mutect2, varscan2
- OPHN1 | c.1738C>T p.R580W | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs765440100; called by muse, mutect2, varscan2
- OVCH1 | c.785G>A p.C262Y | Missense Mutation (SNP) | VAF 71/485 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV100548327; called by muse, mutect2, varscan2
- PATL1 | c.781C>T p.L261F | Missense Mutation (SNP) | VAF 58/279 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.378); catalogued as rs1466702891, COSV100274918; called by muse, mutect2, varscan2
- PCDH15 | c.4843C>A p.R1615S (on ENST00000644397 / NM_001354429.2; = p.R1557S on NM_001142771.2) | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100905868; called by muse, mutect2, varscan2
- PCDHB2 | c.1433C>A p.T478K | Missense Mutation (SNP) | VAF 51/545 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.934); catalogued as rs1554271433; called by muse, mutect2, varscan2
- PDGFRA | c.1411A>C p.N471H | Missense Mutation (SNP) | VAF 72/539 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.45); catalogued as rs758497476; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHLPP1 | c.4147del p.E1383Rfs*70 | Frame Shift Del (DEL) | VAF 22/142 reads (15%) | catalogued as COSV53035317; called by mutect2, pindel, varscan2
- RUNX1 | c.267C>G p.F89L (on ENST00000344691 / NM_001001890.3; = p.F116L on NM_001754.5) | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55872844; called by muse, mutect2, varscan2
- SAMHD1 | c.149T>A p.V50E | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1193287869; called by muse, mutect2, varscan2
- SH2D1A | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 54/614 reads (9%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.098); catalogued as COSV100758296; called by muse, mutect2
- SNAP91 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV52117904; called by muse, mutect2, varscan2
- ST3GAL2 | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 23/131 reads (18%) | PolyPhen benign (0.145); catalogued as rs574593500, COSV100735684; called by muse, mutect2, varscan2
- SYP | c.170G>T p.C57F | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54294643; called by muse, mutect2, varscan2
- TMEM179 | c.272G>T p.R91L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58795744; called by muse, mutect2, varscan2
- TTC24 | c.1588del p.H530Ifs*5 | Frame Shift Del (DEL) | VAF 40/357 reads (11%) | catalogued as rs1387545610, COSV63997938, COSV63998627; called by mutect2, pindel, varscan2
- ZNF717 | c.2063A>G p.H688R | Missense Mutation (SNP) | VAF 68/276 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1188632538; called by muse, mutect2, varscan2
- ADGRL3 | c.998T>C p.L333P (on ENST00000506720 / NM_001322402.2; = p.L265P on NM_015236.6) | Missense Mutation (SNP) | VAF 19/499 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BCL11A | c.1968C>G p.H656Q (on ENST00000335712 / NM_001365609.1; = p.H690Q on NM_018014.4) | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- BTBD8 | c.1894G>T p.G632* (on ENST00000636805 / NM_001376131.1; = p.G119* on NM_015237.4) | Nonsense Mutation (SNP) | VAF 76/445 reads (17%) | called by muse, mutect2, varscan2
- CACNA1F | c.5866G>C p.E1956Q | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- CALCR | c.1473A>T p.*491Cext*2 (on ENST00000649521 / NM_001164737.2; = p.*475Cext*2 on NM_001742.4) | Nonstop Mutation (SNP) | VAF 10/70 reads (14%) | called by mutect2, varscan2
- CCBE1 | c.1132C>A p.P378T | Missense Mutation (SNP) | VAF 130/905 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CCDC70 | c.422A>T p.E141V | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CDH10 | c.1463A>G p.Q488R | Missense Mutation (SNP) | VAF 48/544 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2
- CFAP46 | c.2933C>A p.S978Y | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- CLCN5 | c.115A>G p.K39E | Missense Mutation (SNP) | VAF 32/936 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2
- CORIN | c.2468C>T p.P823L | Missense Mutation (SNP) | VAF 36/259 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- CPEB1 | c.841C>A p.P281T (on ENST00000617958; = p.P221T on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/365 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- CSMD3 | c.9818G>T p.C3273F (on ENST00000297405 / NM_001363185.1; = p.C3104F on NM_052900.3) | Missense Mutation (SNP) | VAF 110/650 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYBB | c.1670G>T p.G557V | Missense Mutation (SNP) | VAF 151/1045 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DMD | c.5523G>T p.E1841D | Missense Mutation (SNP) | VAF 40/1012 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2
- DNAJC3 | c.1070A>T p.D357V | Missense Mutation (SNP) | VAF 37/269 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- DNMBP | c.3655G>T p.A1219S | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- EEF1E1 | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- EEFSEC | c.505A>T p.K169* | Nonsense Mutation (SNP) | VAF 26/290 reads (9%) | called by muse, mutect2
- EFCAB6 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 50/488 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.142); called by muse, mutect2
- EYS | c.2591C>G p.S864* | Nonsense Mutation (SNP) | VAF 87/637 reads (14%) | called by muse, mutect2, varscan2
- FBRSL1 | c.1994G>T p.G665V | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCGR2C | c.151G>T p.V51L | Missense Mutation (SNP) | VAF 23/809 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.143); called by muse, mutect2
- FNIP1 | c.667_681del p.G223_L227del | In Frame Del (DEL) | VAF 36/241 reads (15%) | called by mutect2, pindel, varscan2
- GPR63 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 15/244 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRIK2 | c.2431G>C p.E811Q | Missense Mutation (SNP) | VAF 20/425 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); called by muse, mutect2
- GSTM5 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 64/430 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- IGF1R | c.934A>G p.I312V | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2
- ITGA7 | c.3441C>A p.N1147K (on ENST00000555728; = p.N1103K on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.044); called by muse, varscan2
- KCNH5 | c.861C>G p.N287K | Missense Mutation (SNP) | VAF 50/366 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNN2 | c.410A>T p.Y137F (on ENST00000264773; = p.Y349F on NM_021614.4) | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- KEAP1 | c.476C>G p.A159G | Missense Mutation (SNP) | VAF 56/384 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- KRT6C | c.1582A>T p.S528C | Missense Mutation (SNP) | VAF 70/456 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- KRTAP13-4 | c.296C>G p.S99C | Missense Mutation (SNP) | VAF 41/320 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- LAG3 | c.33T>A p.F11L | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMB4 | c.3294G>T p.Q1098H | Missense Mutation (SNP) | VAF 50/416 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- MAGEB2 | c.242C>A p.S81Y | Missense Mutation (SNP) | VAF 50/304 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- MAGEB6B | c.971T>C p.I324T | Missense Mutation (SNP) | VAF 25/510 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2
- MASP1 | c.1702G>T p.V568L | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- MYH2 | c.2537T>G p.L846W | Missense Mutation (SNP) | VAF 80/514 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- NRG3 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 41/405 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.236); called by muse, mutect2
- NUAK2 | c.1806C>G p.D602E | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); called by muse, varscan2
- NUDT12 | c.379G>T p.D127Y | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NUP160 | c.3697C>G p.Q1233E | Missense Mutation (SNP) | VAF 34/604 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.092); called by muse, mutect2
- OR10J1 | c.862G>T p.V288L | Missense Mutation (SNP) | VAF 52/270 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- OR2A25 | c.563G>T p.C188F | Missense Mutation (SNP) | VAF 41/351 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- OR2M7 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 102/453 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OR2W1 | c.446G>T p.W149L | Missense Mutation (SNP) | VAF 58/295 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OTOL1 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, varscan2
- PHYHIPL | c.978G>C p.Q326H | Missense Mutation (SNP) | VAF 63/400 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PLCL2 | c.1459G>T p.G487C (on ENST00000615277 / NM_001144382.2; = p.G361C on NM_015184.5) | Missense Mutation (SNP) | VAF 40/261 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRODH2 | c.1355G>A p.G452D (on ENST00000301175; = p.G376D on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/412 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); called by muse, mutect2
- R3HDM1 | c.2079C>G p.N693K | Missense Mutation (SNP) | VAF 69/290 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- RASGEF1B | c.79A>T p.S27C | Missense Mutation (SNP) | VAF 34/306 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- RGS3 | c.3202del p.L1068Sfs*17 (on ENST00000350696 / NM_001282923.2; = p.L787Sfs*17 on NM_130795.4) | Frame Shift Del (DEL) | VAF 16/154 reads (10%) | called by mutect2, pindel, varscan2
- RNF215 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RPAP2 | c.941del p.N314Ifs*11 | Frame Shift Del (DEL) | VAF 38/237 reads (16%) | called by mutect2, pindel, varscan2
- RYR2 | c.2068G>A p.A690T | Missense Mutation (SNP) | VAF 116/845 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- SAMD9 | c.1487G>T p.G496V | Missense Mutation (SNP) | VAF 96/1188 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEC16A | c.5103G>C p.W1701C | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SETX | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 98/606 reads (16%) | called by muse, mutect2, varscan2
- SH2D1A | c.372C>A p.C124* | Nonsense Mutation (SNP) | VAF 55/616 reads (9%) | called by muse, mutect2
- SI | c.2410G>T p.V804L | Missense Mutation (SNP) | VAF 115/536 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC34A2 | c.112+3_112+6del p.X38_splice | Splice Site (DEL) | VAF 92/768 reads (12%) | called by pindel, varscan2
- SLC39A12 | c.1802C>A p.T601N (on ENST00000377369 / NM_001145195.2; = p.T564N on NM_152725.3) | Missense Mutation (SNP) | VAF 43/317 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- TMEM185A | c.22C>A p.Q8K | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM41A | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- TRPC5 | c.1756T>A p.Y586N | Missense Mutation (SNP) | VAF 56/404 reads (14%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.501); called by muse, varscan2
- TRUB1 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 47/373 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- UBAP2L | c.947T>C p.F316S | Missense Mutation (SNP) | VAF 65/363 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- UNC80 | c.542C>G p.S181C | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- WASF3 | c.823C>T p.H275Y | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- WNK3 | c.4870+2T>A p.X1624_splice | Splice Site (SNP) | VAF 30/261 reads (11%) | called by muse, mutect2, varscan2
- WNK3 | c.2357C>A p.A786E | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- ZNF664 | c.518G>T p.C173F | Missense Mutation (SNP) | VAF 94/592 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF669 | c.467G>T p.R156I | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, varscan2
- ZNF98 | c.964T>A p.Y322N | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- BTN2A2 | c.252T>G p.G84= | Silent (SNP) | VAF 132/595 reads (22%) | called by muse, mutect2, varscan2
- CARS1 | c.1287G>A p.L429= | Silent (SNP) | VAF 28/142 reads (20%) | called by muse, mutect2, varscan2
- CDH2 | c.924C>A p.I308= | Silent (SNP) | VAF 43/404 reads (11%) | catalogued as COSV52273324; called by muse, mutect2, varscan2
- CHST7 | c.375G>A p.P125= | Silent (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2, varscan2
- DLG3 | c.1983G>C p.R661= (on ENST00000374360 / NM_021120.4; = p.R356= on NM_020730.3) | Silent (SNP) | VAF 70/553 reads (13%) | called by muse, mutect2, varscan2
- FANCF | c.411C>T p.A137= | Silent (SNP) | VAF 32/191 reads (17%) | catalogued as rs751463547; called by muse, mutect2, varscan2
- GLYATL2 | c.396C>T p.L132= | Silent (SNP) | VAF 53/413 reads (13%) | catalogued as rs748599159, COSV99780510; called by muse, mutect2, varscan2
- KMO | c.621C>A p.A207= | Silent (SNP) | VAF 17/360 reads (5%) | called by muse, mutect2
- KNL1 | c.2241A>T p.T747= (on ENST00000346991 / NM_170589.5; = p.T721= on NM_144508.5) | Silent (SNP) | VAF 16/142 reads (11%) | called by muse, mutect2, varscan2
- MTRR | c.1675T>C p.L559= (on ENST00000264668; = p.L532= on NM_002454.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 102/1056 reads (10%) | called by muse, mutect2
- MUC19 | c.294G>A p.T98= | Silent (SNP) | VAF 28/241 reads (12%) | catalogued as rs995871855; called by muse, mutect2, varscan2
- MYH13 | c.4095G>C p.L1365= | Silent (SNP) | VAF 10/256 reads (4%) | called by muse, mutect2
- NEU2 | c.939G>T p.P313= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs748592888, COSV52093700; called by muse, mutect2
- NID1 | c.169C>T p.L57= | Silent (SNP) | VAF 26/255 reads (10%) | called by muse, mutect2, varscan2
- PVRIG | c.159C>T p.T53= | Silent (SNP) | VAF 37/262 reads (14%) | catalogued as rs373639944; called by muse, mutect2, varscan2
- SELENOH | c.366G>T p.S122= | Silent (SNP) | VAF 66/420 reads (16%) | catalogued as rs373869913; called by muse, mutect2, varscan2
- SEMA3E | c.2007C>T p.T669= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs1275768724; called by muse, mutect2, varscan2
- SIGLEC12 | c.234A>T p.T78= | Silent (SNP) | VAF 97/524 reads (19%) | called by muse, mutect2, varscan2
- SLITRK2 | c.879C>T p.L293= | Silent (SNP) | VAF 15/183 reads (8%) | catalogued as rs202041307; called by muse, mutect2
- STRN4 | c.1530G>T p.G510= | Silent (SNP) | VAF 50/330 reads (15%) | called by muse, mutect2, varscan2
- TRPC5 | c.1836C>T p.S612= | Silent (SNP) | VAF 42/358 reads (12%) | catalogued as COSV53293827, COSV53299025; called by muse, varscan2
- ARMCX4 | c.1038+2243C>A | Intron (SNP) | VAF 30/201 reads (15%) | catalogued as COSV61450135; called by muse, mutect2, varscan2
- BRSK2 | c.1939+304del | Intron (DEL) | VAF 25/125 reads (20%) | called by mutect2, pindel, varscan2
- DCHS1 | c.*167C>A | 3'UTR (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- DPY19L1 | c.1101+56G>T | Intron (SNP) | VAF 54/316 reads (17%) | called by muse, varscan2
- FAM53C | chr5:138338125 G>A | 5'Flank (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- IGFLR1 | c.-60G>C | 5'UTR (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- KIR3DX1 | n.41+30G>C | Intron (SNP) | VAF 56/342 reads (16%) | called by muse, mutect2, varscan2
- LINC01591 | n.305T>A | RNA (SNP) | VAF 48/373 reads (13%) | called by muse, mutect2, varscan2
- MAN1B1 | c.328+124A>G | Intron (SNP) | VAF 93/637 reads (15%) | called by muse, mutect2, varscan2
- PCMTD1 | c.-333C>T | 5'UTR (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- POLR2D | c.*7A>G | 3'UTR (SNP) | VAF 123/619 reads (20%) | catalogued as rs1393909476; called by muse, mutect2, varscan2
- SETD4 | c.207+11T>G | Intron (SNP) | VAF 92/496 reads (19%) | called by muse, mutect2, varscan2
- SLC9A6 | c.429+43G>A | Intron (SNP) | VAF 18/500 reads (4%) | called by muse, mutect2
- SRRM2 | c.8021+492G>T | Intron (SNP) | VAF 37/238 reads (16%) | called by muse, mutect2, varscan2
- SSPOP | n.3941G>A | RNA (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- TMTC1 | c.939-27509A>G | Intron (SNP) | VAF 45/386 reads (12%) | called by muse, varscan2
- TUFT1 | c.*506G>T | 3'UTR (SNP) | VAF 31/284 reads (11%) | called by muse, mutect2, varscan2
- UQCR11 | c.-30G>T | 5'UTR (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- VWDE | c.475+231A>T | Intron (SNP) | VAF 41/243 reads (17%) | called by muse, mutect2, varscan2
